Somatic mutation profile of tumor specimen TCGA-DB-A4XD-01A (aliquot TCGA-DB-A4XD-01A-11D-A27K-08) from TCGA case TCGA-DB-A4XD, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Temporal lobe; Tumor grade: G3; Age at diagnosis: 32.1 years (11,741 days).
Specimen TCGA-DB-A4XD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d58b36f-dbd9-4d45-960a-c581c10fbdf0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A4XD-10A (Blood Derived Normal), aliquot TCGA-DB-A4XD-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aebeee3a-19f7-4771-9e2c-ff14ab3648aa

The open-access MAF lists 28 somatic variants for this specimen: 25 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 22, Silent 3, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.595-2A>G p.X199_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | hotspot (GDC flag); catalogued as COSV64870599, COSV64883090, COSV64883867; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 29/70 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 35/40 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV55390267; called by muse, mutect2, varscan2
- ACSBG2 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as rs781480607, COSV53122693; called by muse, mutect2
- BCLAF1 | c.2470A>C p.T824P | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV50356727; called by muse, mutect2
- CPA1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50568072; called by muse, mutect2, varscan2
- DEK | c.926A>C p.D309A | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV55236349; called by muse, mutect2
- KLHL3 | c.817A>G p.M273V | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV59050486; called by muse, mutect2, varscan2
- LONRF2 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV66538934; called by muse, mutect2, varscan2
- MCTP2 | c.1639A>G p.T547A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59140287; called by muse, mutect2
- MEGF8 | c.6553G>A p.G2185R (on ENST00000251268 / NM_001271938.2; = p.G2118R on NM_001410.3) | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1183931335, COSV52073707; called by muse, mutect2, varscan2
- MFHAS1 | c.197A>C p.E66A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV52279505; called by muse, mutect2
- MTARC2 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as COSV63764926, COSV63765556; called by muse, mutect2
- NLRP12 | c.431A>T p.N144I | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV60743136; called by muse, mutect2, varscan2
- PCDHB3 | c.281A>G p.E94G | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.918); catalogued as COSV50563902; called by muse, mutect2
- SERPINH1 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as COSV63997586; called by muse, mutect2, varscan2
- SLC6A3 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769500824, COSV54361185; called by muse, mutect2, varscan2
- SLCO1B1 | c.345T>A p.H115Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV57006530; called by muse, mutect2, varscan2
- SNAPC4 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775575481, COSV53730419; called by muse, mutect2, varscan2
- TBX10 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 25/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs535008516, COSV56874936; called by muse, mutect2
- TTLL2 | c.53T>C p.L18S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53442395; called by muse, mutect2, varscan2
- USP44 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs781541174, COSV51561407; called by muse, mutect2, varscan2
- VIRMA | c.5114G>A p.R1705K | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV52581314; called by muse, mutect2
- ATRX | c.2978del p.K993Rfs*10 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.1059C>T p.P353= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV54839446; called by muse, mutect2, varscan2
- KANK1 | c.2427G>A p.E809= | Silent (SNP) | VAF 17/199 reads (9%) | catalogued as COSV63209322; called by muse, mutect2
- SLC52A3 | c.702C>T p.C234= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV54076475; called by muse, mutect2
